Somatic mutation profile of tumor specimen TCGA-AA-3966-01A (aliquot TCGA-AA-3966-01A-01W-1073-09) from TCGA case TCGA-AA-3966, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 89.1 years (32,537 days).
Specimen TCGA-AA-3966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a9dd08-6a58-47f3-b956-86091e1dc937.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3966-10A (Blood Derived Normal), aliquot TCGA-AA-3966-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef109fa9-a2c7-49ca-b49f-9d55267cf12b

The open-access MAF lists 1,375 somatic variants for this specimen: 1,078 protein-altering or splice-affecting, 269 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 728, Silent 269, Frame Shift Del 237, Frame Shift Ins 43, Nonsense Mutation 38, Splice Site 20, Intron 14, In Frame Del 5, RNA 5, Splice Region 5, 5'Flank 5, 3'UTR 3.

Variants (750 of 1,375; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309del p.D1104Mfs*214 | Frame Shift Del (DEL) | VAF 48/180 reads (27%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 44/158 reads (28%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- EGFR | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as rs150036236, COSV51801471; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EPG5 | c.6020_6021del p.C2007Yfs*2 | Frame Shift Del (DEL) | VAF 49/167 reads (29%) | catalogued as rs1064795230; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 74/223 reads (33%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 72/371 reads (19%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH2 | c.3246dup p.A1083Sfs*17 | Frame Shift Ins (INS) | VAF 19/152 reads (13%) | catalogued as rs1553195973; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SEC63 | c.452+1G>A p.X151_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as rs869312977, COSV100938292; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 22/80 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 26/82 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- AASS | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.961); catalogued as rs868487258, COSV62790109; called by muse, mutect2, varscan2
- ABCA12 | c.5399C>T p.T1800M (on ENST00000272895 / NM_173076.3; = p.T1482M on NM_015657.3) | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs541331115, COSV55955972; called by muse, mutect2, varscan2
- ABCA13 | c.10358T>G p.L3453W | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV71288234; called by muse, mutect2, varscan2
- ABCA4 | c.6386G>T p.S2129I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV64673711; called by muse, mutect2, varscan2
- ABCA8 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV52201741; called by muse, mutect2, varscan2
- ABCC11 | c.1967T>G p.L656R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323219; called by muse, mutect2, varscan2
- ABCC11 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746920060, COSV62323226; called by muse, mutect2, varscan2
- ABLIM1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs202220476, COSV53301485, COSV99522116; called by muse, mutect2, varscan2
- ACAD10 | c.2704G>T p.G902C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58157424, COSV58163505; called by muse, mutect2, varscan2
- ACTR1A | c.987+2T>C p.X329_splice | Splice Site (SNP) | VAF 40/157 reads (25%) | catalogued as COSV99487676; called by muse, mutect2, varscan2
- ACVR1C | c.914A>C p.H305P | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54646355; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 132/205 reads (64%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs765853980, COSV61702301; called by muse, mutect2, varscan2
- ADAD1 | c.959T>A p.I320N | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV56643690; called by muse, mutect2, varscan2
- ADAMTS3 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs557435473, COSV54388875; called by muse, mutect2, varscan2
- ADAMTS3 | c.2644C>A p.H882N | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV54391894, COSV54406140; called by muse, mutect2, varscan2
- ADAMTSL1 | c.724A>G p.S242G | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as rs752983559, COSV52816021; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | catalogued as COSV65879385; called by mutect2, pindel
- ADAT1 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs754878846, COSV57186673; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 114/187 reads (61%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRF1 | c.1979C>A p.A660D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99346875; called by muse, mutect2, varscan2
- ADGRV1 | c.15415G>A p.E5139K | Missense Mutation (SNP) | VAF 122/280 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs776241274, COSV67985546; called by muse, mutect2, varscan2
- AFAP1 | c.2035T>G p.S679A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.626); catalogued as rs768168136, COSV61795712; called by muse, mutect2, varscan2
- AGBL1 | c.2269T>G p.F757V | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV66852044; called by muse, mutect2
- AGO1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774432228, COSV64595117; called by muse, mutect2, varscan2
- AGPAT3 | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52370470, COSV99377464; called by muse, mutect2, varscan2
- AHCTF1 | c.295C>T p.R99* (on ENST00000366508; = p.R73* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV58250416; called by muse, mutect2, varscan2
- AHCY | c.722T>C p.I241T | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as COSV54153247; called by muse, mutect2, varscan2
- AHNAK | c.5879T>C p.V1960A | Missense Mutation (SNP) | VAF 121/366 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV57214181; called by muse, mutect2, varscan2
- AIFM1 | c.350-2A>G p.X117_splice | Splice Site (SNP) | VAF 80/155 reads (52%) | catalogued as COSV99780675; called by muse, mutect2, varscan2
- AKAP4 | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62074484; called by muse, mutect2, varscan2
- AL121899.2 | c.1393T>G p.S465A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67350705; called by muse, mutect2, varscan2
- ALDH7A1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs771975420, COSV63160888; called by muse, mutect2, varscan2
- ALOXE3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs144996877, COSV59074427; called by muse, mutect2, varscan2
- ALPK1 | c.1400G>T p.C467F | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV51585189; called by muse, mutect2, varscan2
- AMOTL1 | c.1980A>C p.E660D | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV58566798; called by muse, mutect2, varscan2
- ANAPC7 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs372040468; called by muse, mutect2, varscan2
- ANGPT2 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV57337104; called by muse, mutect2, varscan2
- ANGPT4 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV67922627; called by muse, mutect2
- ANKAR | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs757357867, COSV55612940; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 40/78 reads (51%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs1296524808; called by mutect2, varscan2
- AOC3 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs781215948, COSV53826712; called by muse, mutect2, varscan2
- AP1G2 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58112806; called by muse, mutect2, varscan2
- AP3B1 | c.2762A>G p.E921G | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753810749, COSV54876118, COSV54884208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APMAP | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99468084; called by muse, mutect2
- AQP4 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67218677; called by muse, mutect2, varscan2
- ARFIP2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV54446838; called by muse, mutect2, varscan2
- ARHGAP21 | c.4094T>C p.I1365T | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV57605886; called by muse, mutect2, varscan2
- ARHGEF12 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100754562; called by muse, mutect2, varscan2
- ARHGEF39 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV58397176; called by muse, mutect2, varscan2
- ARHGEF9 | c.1130A>G p.E377G | Missense Mutation (SNP) | VAF 105/659 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV53638475; called by muse, mutect2, varscan2
- ARID1B | c.5680A>G p.I1894V | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99266621; called by muse, mutect2, varscan2
- ARMC2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 477/884 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs775864051, COSV64551289; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 54/159 reads (34%) | catalogued as rs772181094; called by mutect2, varscan2
- ASAP1 | c.1091A>G p.Q364R | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100726762; called by muse, mutect2
- ASB5 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56670786, COSV56671107; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 112/194 reads (58%) | catalogued as rs747570359; called by mutect2, varscan2
- ASH1L | c.8273C>T p.T2758I (on ENST00000368346 / NM_001366177.2; = p.T2753I on NM_018489.3) | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.966); catalogued as rs202229139, COSV64208170; called by muse, mutect2, varscan2
- ASMT | c.857T>C p.L286P (on ENST00000381229; = p.L314P on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV67109867; called by muse, mutect2, varscan2
- ATAD5 | c.2593A>G p.T865A | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58974826, COSV58977964; called by muse, mutect2, varscan2
- ATG14 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55956621; called by muse, mutect2, varscan2
- ATG4A | c.295T>G p.W99G | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV58965669; called by muse, mutect2, varscan2
- ATM | c.6179G>A p.R2060H | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs376521407, COSV53745356; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ATP13A2 | c.2171T>C p.M724T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs774661817, COSV58700812; called by muse, mutect2, varscan2
- ATP1A3 | c.1904G>T p.G635V (on ENST00000545399 / NM_001256214.2; = p.G622V on NM_152296.5) | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100131830; called by muse, mutect2
- ATP2B4 | c.3174G>T p.K1058N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.233); catalogued as COSV58178076; called by muse, mutect2, varscan2
- ATP4A | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs754720662, COSV52868160; called by muse, mutect2, varscan2
- ATP6V0D2 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774964031, COSV53413041; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as COSV52269525; called by muse, mutect2, varscan2
- ATXN2 | c.3933G>T p.Q1311H (on ENST00000550104; = p.Q1151H on NM_002973.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57983468; called by muse, mutect2, varscan2
- ATXN7L2 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs185034916, COSV60204908; called by muse, mutect2, varscan2
- AVIL | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1460576474, COSV57681919; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1134G>T p.W378C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50056092; called by muse, mutect2, varscan2
- BAZ2B | c.816A>T p.E272D | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.026); catalogued as rs1402517839, COSV58601173; called by muse, mutect2, varscan2
- BBS7 | c.1063A>C p.K355Q | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV99144786; called by muse, mutect2
- BBS7 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99144787; called by muse, mutect2
- BDNF | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.989); catalogued as COSV59235010; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as rs752427670; called by mutect2, varscan2
- BEX5 | c.113T>G p.V38G | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61328459; called by muse, varscan2
- BIRC6 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1177083040, COSV70195605; called by muse, mutect2
- BMPR1A | c.1379T>C p.M460T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as rs758309022, COSV64406206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR1B | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs377000102, COSV52777569, COSV52777734; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOD1L1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs768340636, COSV50012031; called by muse, mutect2, varscan2
- BPIFB4 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs779054648, COSV64950908, COSV64951234; called by muse, mutect2, varscan2
- BPTF | c.3259del p.I1087* | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs757520968; called by mutect2, varscan2
- BRINP3 | c.445A>T p.I149F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100818221, COSV66524697; called by muse, mutect2, varscan2
- BSN | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99607020; called by muse, mutect2, varscan2
- BTBD16 | c.729dup p.T244Dfs*26 | Frame Shift Ins (INS) | VAF 19/79 reads (24%) | catalogued as rs774408792; called by pindel, varscan2
- BTBD9 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58426293; called by muse, mutect2, varscan2
- BTN1A1 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 115/261 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55067764; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C6orf118 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV57815181; called by muse, mutect2, varscan2
- C6orf136 | c.557G>A p.R186H (on ENST00000376473 / NM_001109938.3; = p.R52H on NM_145029.4) | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as rs376377195; called by muse, mutect2, varscan2
- C8B | c.1031A>G p.Y344C | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64776352; called by muse, mutect2, varscan2
- CABIN1 | c.1912T>C p.Y638H | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54081986; called by muse, mutect2, varscan2
- CACHD1 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.972); catalogued as rs753954534, COSV51553557; called by muse, mutect2, varscan2
- CACNA1C | c.6442G>A p.A2148T (on ENST00000399634 / NM_001167625.1; = p.A2077T on NM_000719.7) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs745761632, COSV59721006; called by muse, mutect2, varscan2
- CACNA1D | c.1370_1372del p.G457del | In Frame Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs767282463; called by pindel, varscan2
- CACNA1F | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151203138, COSV59904563; called by muse, mutect2, varscan2
- CACNA1F | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs782280160, COSV59904568; called by muse, mutect2, varscan2
- CACNG1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs918445063, COSV56826836; called by muse, mutect2
- CADM1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs1471338171, COSV59010737; called by muse, mutect2, varscan2
- CADM2 | c.598G>A p.A200T (on ENST00000407528 / NM_001167674.2; = p.A202T on NM_153184.4) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.342); catalogued as rs1333409387, COSV67375650; called by muse, mutect2, varscan2
- CADPS | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51867195, COSV51886367; called by muse, mutect2, varscan2
- CALB2 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56939507; called by muse, mutect2, varscan2
- CAPRIN2 | c.3057G>T p.E1019D | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51832645; called by muse, mutect2, varscan2
- CASD1 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51972587; called by muse, mutect2
- CCAR1 | c.1130A>G p.D377G | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV56269953; called by muse, mutect2, varscan2
- CCDC144A | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV60698451, COSV60698573; called by muse, mutect2, varscan2
- CCDC15 | c.581dup p.S196Ifs*6 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | catalogued as rs759789184; called by mutect2, varscan2
- CCDC170 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV53341000; called by muse, mutect2, varscan2
- CCDC77 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280483392, COSV53473066; called by muse, mutect2, varscan2
- CCR8 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as COSV58337254; called by muse, mutect2, varscan2
- CCT8L2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs368696107; called by muse, mutect2, varscan2
- CD200R1L | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 99/244 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV68004284; called by muse, mutect2, varscan2
- CD34 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV60413034; called by muse, mutect2, varscan2
- CDC25B | c.1028A>G p.D343G (on ENST00000245960 / NM_021873.3; = p.D329G on NM_004358.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55656750; called by muse, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH6 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 186/437 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54066466, COSV54070403; called by muse, mutect2, varscan2
- CDON | c.2625del p.S875Rfs*8 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | catalogued as COSV54998106; called by mutect2, pindel, varscan2
- CEACAM18 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs371514477, COSV67282652; called by muse, mutect2, varscan2
- CEACAM19 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100715540, COSV62552013; called by muse, mutect2, varscan2
- CEP164 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV54041486; called by muse, mutect2, varscan2
- CEP192 | c.3874G>T p.G1292* | Nonsense Mutation (SNP) | VAF 59/199 reads (30%) | catalogued as COSV58064568; called by muse, mutect2, varscan2
- CFAP44 | c.14A>T p.D5V | Missense Mutation (SNP) | VAF 69/293 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV55611570; called by muse, mutect2, varscan2
- CFAP47 | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs1339667296, COSV52884827; called by muse, mutect2, varscan2
- CFAP53 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV68351986; called by muse, mutect2, varscan2
- CFAP94 | c.1223T>C p.I408T (on ENST00000320267 / NM_001352064.2; = p.I414T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV57232344; called by muse, mutect2, varscan2
- CGN | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs762534512, COSV54970081; called by muse, mutect2, varscan2
- CHD6 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 64/144 reads (44%) | catalogued as COSV58557334; called by muse, mutect2, varscan2
- CHPF | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs552002112, COSV60534800; called by muse, mutect2
- CHST14 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.833); catalogued as rs1207935361, COSV60378824; called by muse, mutect2, varscan2
- CHST5 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs769565596, COSV60337156; called by muse, mutect2, varscan2
- CIT | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs538911447, COSV55869410; called by muse, mutect2, varscan2
- CIT | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1475867999, COSV55869422; called by muse, mutect2, varscan2
- CLDN8 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54525961; called by muse, mutect2, varscan2
- CLEC12A | c.223dup p.M75Nfs*9 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs756570750; called by mutect2, varscan2
- CLEC14A | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs558964656, COSV60562592; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPB | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV53629998; called by muse, mutect2, varscan2
- CLSTN2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs766373799, COSV71719763; called by muse, mutect2, varscan2
- CLYBL | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs200083846, COSV59221946; called by muse, mutect2, varscan2
- CMYA5 | c.4226A>G p.E1409G | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV71406037; called by muse, mutect2, varscan2
- CNKSR1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs751252460, COSV64163060; called by muse, mutect2, varscan2
- CNNM4 | c.1351T>G p.F451V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV65660942; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 72/248 reads (29%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as rs374805044; called by mutect2, varscan2
- COBLL1 | c.677T>C p.L226P (on ENST00000392717; = p.L188P on NM_014900.5) | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1457740449, COSV52068159; called by muse, mutect2, varscan2
- COG7 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs764545607, COSV56150354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A1 | c.3926A>G p.Q1309R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56805179; called by muse, mutect2, varscan2
- COL1A1 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56804614, COSV56805195; called by muse, mutect2, varscan2
- COL1A2 | c.3744G>T p.K1248N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV51958470, COSV51964873; called by muse, varscan2
- COL4A4 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV61632394; called by muse, mutect2, varscan2
- COQ8B | c.20del p.G7Afs*69 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | catalogued as rs763451274; called by mutect2, varscan2
- CORIN | c.2917T>C p.Y973H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56691766; called by muse, mutect2, varscan2
- COX10 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV55405120; called by muse, varscan2
- CPNE4 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV70194455; called by muse, mutect2, varscan2
- CPXM2 | c.2131del p.A711Pfs*35 | Frame Shift Del (DEL) | VAF 63/206 reads (31%) | catalogued as COSV99581978; called by mutect2, pindel, varscan2
- CRACD | c.3104C>T p.A1035V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1391473006, COSV51714583; called by muse, mutect2
- CRADD | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60553600; called by muse, mutect2, varscan2
- CREBBP | c.2516A>G p.Q839R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.418); catalogued as COSV52124411; called by muse, mutect2, varscan2
- CRYBG1 | c.5890C>T p.R1964* | Nonsense Mutation (SNP) | VAF 42/164 reads (26%) | catalogued as rs373572080, COSV64812540; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSMD1 | c.2787T>A p.A929= (on ENST00000520002; = p.A928= on NM_033225.6) | Splice Region (SNP) | VAF 29/65 reads (45%) | catalogued as COSV59326523; called by muse, mutect2, varscan2
- CSMD2 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs200976511, COSV53914025; called by muse, mutect2, varscan2
- CSMD3 | c.8361G>T p.L2787F (on ENST00000297405 / NM_001363185.1; = p.L2618F on NM_052900.3) | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as COSV52185633; called by muse, mutect2, varscan2
- CSMD3 | c.7223C>T p.T2408M (on ENST00000297405 / NM_001363185.1; = p.T2304M on NM_052900.3) | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs370458785; called by muse, mutect2, varscan2
- CSNK1A1L | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.363); catalogued as COSV65789716; called by muse, mutect2, varscan2
- CTNNA1 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV57074133; called by muse, mutect2, varscan2
- CTNNA2 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as COSV63568759; called by muse, mutect2, varscan2
- CTNNA3 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs1195868563, COSV65583983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs780976546, COSV63727691, COSV63728320, COSV63728637; called by muse, mutect2, varscan2
- CUL2 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV66079291; called by muse, mutect2, varscan2
- CUL9 | c.1292G>A p.W431* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as rs772155541, COSV52728749; called by muse, mutect2, varscan2
- CUX2 | c.4229T>A p.V1410E | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as COSV55632727; called by muse, mutect2, varscan2
- CWC27 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751858333, COSV66885913, COSV66885937; called by muse, mutect2, varscan2
- CYFIP2 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV59036688, COSV59038387; called by muse, mutect2, varscan2
- CYP2A13 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV57837912; called by muse, mutect2, varscan2
- DARS2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1277759672, COSV53407129; called by muse, mutect2, varscan2
- DCLK1 | c.1408-1G>A p.X470_splice | Splice Site (SNP) | VAF 38/123 reads (31%) | catalogued as COSV55189781, COSV99708696, COSV99711209; called by muse, mutect2, varscan2
- DCN | c.849A>C p.R283S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99271694; called by muse, mutect2, varscan2
- DCST1 | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs202162660, COSV55063674; called by muse, varscan2
- DDX19A | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56359968; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 69/136 reads (51%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX5 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56747738, COSV99858180; called by muse, mutect2, varscan2
- DDX56 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV51836667; called by muse, mutect2, varscan2
- DDX58 | c.1487T>C p.L496S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV101152373; called by muse, mutect2, varscan2
- DENND4A | c.4322A>G p.Y1441C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV71265889; called by muse, mutect2, varscan2
- DENND5B | c.2360G>T p.R787M | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60902697, COSV60908908; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHRS7C | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV57650855; called by muse, mutect2, varscan2
- DIDO1 | c.2214+2T>C p.X738_splice | Splice Site (SNP) | VAF 36/112 reads (32%) | catalogued as COSV99824453; called by muse, mutect2, varscan2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- DLG5 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100967195; called by muse, mutect2, varscan2
- DMD | c.1909A>G p.T637A | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55872433; called by muse, mutect2, varscan2
- DMKN | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV60086400; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.8837C>T p.A2946V (on ENST00000409039; = p.A2885V on NM_207437.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs201720388, COSV68994148; called by muse, mutect2, varscan2
- DNAH17 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1321412708, COSV101101190; called by muse, varscan2
- DNAH8 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs781704190, COSV59446862; called by muse, mutect2, varscan2
- DNAI1 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 37/136 reads (27%) | catalogued as COSV99646496; called by muse, mutect2, varscan2
- DNAJB4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV66131594; called by muse, mutect2, varscan2
- DNAJB8 | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100048054; called by muse, mutect2, varscan2
- DNAJC11 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as rs999766150, COSV53786833; called by muse, mutect2
- DNAJC22 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101222492; called by muse, mutect2, varscan2
- DNAJC8 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs757585832, COSV55281620; called by muse, mutect2, varscan2
- DNER | c.1878C>A p.H626Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV59166660; called by muse, mutect2, varscan2
- DNHD1 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV54436051; called by muse, mutect2, varscan2
- DOCK2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953545; called by muse, mutect2, varscan2
- DOCK2 | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56959556; called by muse, mutect2, varscan2
- DOCK3 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs766088466, COSV56522340; called by muse, mutect2, varscan2
- DOCK3 | c.4123T>C p.C1375R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV56522351; called by muse, mutect2, varscan2
- DOK5 | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52819240, COSV52820421, COSV52823946; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 30/194 reads (15%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DSG1 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57135430; called by muse, mutect2, varscan2
- DST | c.20510G>A p.R6837H (on ENST00000361203 / NM_001374722.1; = p.R4534H on NM_015548.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs576138885, COSV55015580; called by muse, mutect2
- DZIP3 | c.2095A>G p.S699G | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64312145; called by muse, mutect2, varscan2
- E2F8 | c.1380A>C p.K460N | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV51463631; called by muse, mutect2, varscan2
- ECSIT | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as rs778037100, COSV52939464; called by muse, mutect2, varscan2
- ECT2L | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV100871733; called by muse, mutect2, varscan2
- EDN3 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV61108053; called by muse, mutect2, varscan2
- EEPD1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs140394885; called by muse, mutect2, varscan2
- EIF2AK3 | c.1847A>T p.D616V | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57547938; called by muse, mutect2, varscan2
- EIF2AK4 | c.2567dup p.L856Ffs*4 | Frame Shift Ins (INS) | VAF 85/193 reads (44%) | catalogued as rs35250897; called by mutect2, varscan2
- ELAPOR1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV64040475; called by muse, mutect2, varscan2
- ELAPOR2 | c.1208A>G p.Y403C (on ENST00000450689 / NM_001142749.3; = p.Y236C on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/360 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV51887096; called by muse, mutect2, varscan2
- EML5 | c.3313A>G p.S1105G | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV61345808; called by muse, mutect2, varscan2
- ENKD1 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV54667736; called by muse, mutect2, varscan2
- EPC1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV53925441; called by muse, mutect2
- EPHA3 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as rs758342526, COSV60706580; called by muse, mutect2, varscan2
- EPHA7 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV65183015; called by muse, mutect2, varscan2
- EPRS1 | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1433471935, COSV65099055; called by muse, mutect2, varscan2
- ERBB4 | c.1590G>T p.R530S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV53505008, COSV53510629, COSV53533788; called by muse, mutect2, varscan2
- ERICH3 | c.987A>C p.K329N | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV58607059; called by muse, mutect2, varscan2
- ESPL1 | c.5092C>T p.R1698C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1473544704, COSV57759574; called by muse, mutect2, varscan2
- ESPL1 | c.5712G>T p.W1904C | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228763; called by muse, mutect2, varscan2
- ETF1 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV62127343; called by muse, mutect2, varscan2
- ETV6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs745867456, COSV67150238; called by muse, mutect2, varscan2
- EXOC6B | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 89/664 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs201814463, COSV55555703; called by muse, varscan2
- F13A1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV53558729, COSV99343827; called by muse, mutect2, varscan2
- F2 | c.1473-1G>A p.X491_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100319285; called by muse, mutect2, varscan2
- FABP4 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.5); catalogued as COSV56269018; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM111A | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs748374095, COSV64655368; called by muse, mutect2, varscan2
- FAM149A | c.1040A>C p.H347P (on ENST00000356371 / NM_001367768.2; = p.H56P on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV57027424; called by muse, mutect2, varscan2
- FAM209A | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54767090; called by muse, mutect2, varscan2
- FAM20B | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs773926718, COSV55380376; called by muse, mutect2, varscan2
- FAM47C | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs145034356, COSV100792224, COSV63724689; called by muse, mutect2, varscan2
- FANCB | c.1547C>A p.S516Y | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV60759963; called by muse, mutect2, varscan2
- FANCF | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs758608960, COSV59416340; called by muse, mutect2, varscan2
- FANCM | c.4868T>G p.V1623G | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV57501351; called by muse, mutect2, varscan2
- FAT2 | c.12127del p.D4043Tfs*8 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as COSV99941906; called by mutect2, pindel, varscan2
- FAT2 | c.10436C>A p.P3479Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs372161810, COSV55819509, COSV55820103; called by muse, mutect2, varscan2
- FAT3 | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53112608; called by muse, varscan2
- FAT3 | c.2143T>G p.F715V | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV53112635, COSV53165730; called by muse, varscan2
- FAT4 | c.12238T>C p.C4080R | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100627027; called by muse, mutect2
- FAT4 | c.13434del p.K4479Rfs*15 | Frame Shift Del (DEL) | VAF 40/131 reads (31%) | catalogued as COSV58708215; called by mutect2, pindel, varscan2
- FBN2 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV52514372; called by muse, mutect2, varscan2
- FBXO16 | c.26del p.N9Tfs*11 | Frame Shift Del (DEL) | VAF 53/238 reads (22%) | catalogued as rs770129495; called by mutect2, pindel, varscan2
- FBXO30 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 223/410 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52791300; called by muse, mutect2, varscan2
- FBXO32 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756822475, COSV54891111; called by muse, mutect2, varscan2
- FCGBP | c.447del p.G150Afs*25 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs765680504; called by mutect2, pindel
- FCRL3 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs767160539, COSV63841683; called by muse, mutect2, varscan2
- FCRL3 | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV63841692; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 50/220 reads (23%) | catalogued as rs748969702; called by mutect2, varscan2
- FHOD3 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57173747; called by muse, mutect2, varscan2
- FHOD3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs960627486, COSV57173045, COSV99942301; called by muse, mutect2, varscan2
- FLT1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV56728367, COSV56741828; called by muse, mutect2, varscan2
- FNBP4 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55448750; called by muse, mutect2, varscan2
- FOXD4L4 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1159773491; called by mutect2, varscan2
- FSTL1 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV55233816; called by muse, mutect2, varscan2
- FTHL17 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs748357093, COSV63266985; called by muse, mutect2
- FUT3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757862405, COSV54605943; called by muse, mutect2, varscan2
- FUT6 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs375534466; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 32/85 reads (38%) | catalogued as rs756304971; called by mutect2, varscan2
- GABPB2 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64460916; called by muse, mutect2, varscan2
- GABRB3 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54665030; called by muse, mutect2, varscan2
- GABRG3 | c.1370A>G p.N457S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV61518657; called by muse, mutect2, varscan2
- GAD2 | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52157790, COSV52167358; called by muse, mutect2, varscan2
- GALNT17 | c.1647C>A p.Y549* | Nonsense Mutation (SNP) | VAF 53/134 reads (40%) | catalogued as COSV61163084; called by muse, mutect2, varscan2
- GAS2L3 | c.1999A>G p.S667G | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57157376; called by muse, mutect2, varscan2
- GATA1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64962318; called by muse, mutect2, varscan2
- GBA2 | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV62305858; called by muse, mutect2, varscan2
- GBP2 | c.1254_1256del p.E418del | In Frame Del (DEL) | VAF 84/284 reads (30%) | catalogued as rs765107402; called by pindel, varscan2
- GFOD2 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV52057974; called by muse, mutect2, varscan2
- GFPT2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs370818985; called by muse, mutect2, varscan2
- GLB1L3 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs755934137, COSV68392765; called by muse, mutect2, varscan2
- GLI3 | c.4541A>G p.D1514G | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101229684; called by muse, mutect2
- GLRB | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV52417025; called by muse, mutect2, varscan2
- GNA14 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59023935, COSV59029715; called by muse, mutect2, varscan2
- GNB1 | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV101060726; called by muse, mutect2, varscan2
- GNL1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs757866378, COSV64835225; called by muse, mutect2, varscan2
- GOT1L1 | c.870dup p.N291Qfs*89 | Frame Shift Ins (INS) | VAF 17/42 reads (40%) | catalogued as rs768946390; called by mutect2, varscan2
- GPAA1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs369617537, COSV60155766; called by muse, mutect2, varscan2
- GPD1L | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as COSV56990135; called by muse, mutect2, varscan2
- GPHN | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as rs530173903, COSV59480870; called by muse, varscan2
- GPR149 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV67667416; called by muse, mutect2, varscan2
- GPR52 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1453719313, COSV52296355; called by muse, mutect2, varscan2
- GRAMD2B | c.1288A>G p.N430D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV53507592; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 35/234 reads (15%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.699); catalogued as rs1191383047, COSV70802377, COSV70802702; called by muse, mutect2, varscan2
- GRIN3A | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs199945164, COSV62453970; called by muse, mutect2, varscan2
- GRIPAP1 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV64552099; called by muse, mutect2, varscan2
- GRM1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 117/195 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51112717; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2566G>A p.D856N (on ENST00000265755 / NM_016328.3; = p.D841N on NM_005685.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs782620258, COSV56086567, COSV56090067; called by muse, mutect2, varscan2
- GUCA1A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1356867260, COSV50004198; called by muse, mutect2, varscan2
- GUCY1A1 | c.125C>A p.A42E | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.042); catalogued as COSV99636961; called by muse, mutect2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 16/106 reads (15%) | catalogued as COSV54945907; called by mutect2, varscan2
- GYPB | c.61A>C p.S21R | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs180889318; called by muse, varscan2
- HACE1 | c.1478G>T p.R493I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53502589; called by muse, mutect2, varscan2
- HDHD3 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs772718812, COSV53057216; called by muse, mutect2, varscan2
- HECTD4 | c.13216G>A p.A4406T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV66392363; called by muse, mutect2, varscan2
- HECTD4 | c.7261G>A p.V2421I | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs768805905, COSV66392366; called by muse, mutect2, varscan2
- HELB | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 120/319 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1267788399, COSV56071957; called by muse, mutect2, varscan2
- HELQ | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751377136, COSV55025334; called by muse, mutect2, varscan2
- HERC2 | c.13478T>G p.L4493R | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55324519; called by muse, mutect2, varscan2
- HERC2 | c.4282C>T p.P1428S | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.979); catalogued as COSV55324530; called by muse, mutect2, varscan2
- HERC6 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1478737280, COSV52030267; called by muse, mutect2, varscan2
- HGD | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99380526; called by muse, mutect2, varscan2
- HGF | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949909; called by muse, mutect2, varscan2
- HLA-G | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.506); catalogued as COSV64405721; called by muse, mutect2, varscan2
- HLCS | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60793784; called by muse, mutect2, varscan2
- HMOX1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768800478, COSV53339862; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 32/70 reads (46%) | catalogued as rs755016625; called by mutect2, varscan2
- HS6ST3 | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65011698; called by muse, mutect2, varscan2
- HSD17B10 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 29/197 reads (15%) | catalogued as COSV51448069; called by muse, mutect2, varscan2
- HSF2 | c.648A>G p.I216M | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV63773938; called by muse, mutect2, varscan2
- HSPA9 | c.1665A>C p.K555N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV51864491; called by muse, mutect2, varscan2
- HTR1F | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60389746; called by muse, mutect2, varscan2
- HTT | c.6869G>T p.G2290V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV61862433; called by muse, mutect2, varscan2
- HUWE1 | c.4223G>T p.R1408L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV53346175; called by muse, mutect2, varscan2
- HYOU1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as rs782034654, COSV68215840; called by muse, mutect2, varscan2
- IARS2 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV56959868; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM1 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV53425146; called by muse, mutect2, varscan2
- IFT172 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 103/426 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327376049, COSV53133903; called by muse, mutect2, varscan2
- IFT80 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs754818191, COSV58447770; called by muse, mutect2, varscan2
- IGFBP3 | c.746A>T p.K249M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51872434; called by muse, mutect2, varscan2
- IGHV2-70 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.743); catalogued as rs61732216; called by mutect2, varscan2
- IKZF2 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 118/315 reads (37%) | catalogued as COSV59578755, COSV59584959; called by muse, mutect2, varscan2
- IL12RB2 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 49/722 reads (7%) | catalogued as COSV99254553; called by muse, mutect2
- ILDR1 | c.1487G>A p.R496H (on ENST00000344209 / NM_001199799.2; = p.R452H on NM_175924.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs757986659, COSV56550175; called by muse, mutect2
- ILVBL | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54619754; called by muse, mutect2, varscan2
- IMMT | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV54487100; called by muse, mutect2, varscan2
- INPP5F | c.788del p.P263Lfs*7 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs750419826; called by mutect2, pindel, varscan2
- INPPL1 | c.2950C>A p.P984T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs892095304, COSV53353388, COSV53355693; called by muse, mutect2, varscan2
- INSR | c.1750A>G p.K584E | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57163138; called by muse, mutect2, varscan2
- INTS10 | c.1613C>A p.S538* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV67604249; called by muse, mutect2, varscan2
- INTS13 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 185/504 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1403909653, COSV53902698; called by muse, mutect2, varscan2
- IQCF1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778155817, COSV58823457; called by muse, mutect2, varscan2
- ITGAM | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147195093; called by muse, mutect2, varscan2
- ITGB2 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV56610275; called by muse, mutect2, varscan2
- ITIH5 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs112992012; called by muse, mutect2, varscan2
- ITIH6 | c.2728A>C p.S910R | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54489273, COSV54495560; called by muse, mutect2, varscan2
- ITLN2 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV63537780; called by muse, mutect2, varscan2
- ITPRID1 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60075147; called by muse, mutect2, varscan2
- JAKMIP2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54599965; called by muse, mutect2, varscan2
- JCAD | c.3595A>T p.K1199* | Nonsense Mutation (SNP) | VAF 83/190 reads (44%) | catalogued as COSV64759716; called by muse, mutect2, varscan2
- KALRN | c.7753G>A p.V2585M (on ENST00000360013 / NM_001024660.4; = p.V888M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373744782, COSV52248952; called by muse, mutect2, varscan2
- KANSL1 | c.2762C>T p.A921V (on ENST00000574590 / NM_001193465.2; = p.A922V on NM_015443.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs1325326306, COSV52240617; called by muse, mutect2, varscan2
- KAT6B | c.5789C>T p.A1930V | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as rs767826139, COSV54745244; called by muse, mutect2, varscan2
- KATNAL1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs762143192, COSV66063339; called by muse, mutect2, varscan2
- KATNIP | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs749729955, COSV55180953; called by muse, mutect2, varscan2
- KCNA3 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63901626; called by muse, mutect2, varscan2
- KCNA4 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV60252420; called by muse, mutect2, varscan2
- KCND2 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV58580665; called by muse, mutect2, varscan2
- KCNH7 | c.85T>A p.F29I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59791047; called by muse, mutect2, varscan2
- KDM3B | c.3118A>G p.N1040D | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58690845; called by muse, mutect2, varscan2
- KDM5A | c.4946A>T p.E1649V | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66992519; called by muse, mutect2, varscan2
- KIAA0232 | c.3226C>A p.L1076I | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV56925495; called by muse, mutect2, varscan2
- KIAA1109 | c.11859A>T p.K3953N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52674163; called by muse, mutect2, varscan2
- KIAA1958 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1218340281, COSV61723772; called by muse, mutect2, varscan2
- KIF13A | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV52451674; called by muse, mutect2, varscan2
- KIF14 | c.4444C>T p.Q1482* | Nonsense Mutation (SNP) | VAF 49/105 reads (47%) | catalogued as COSV66261841; called by muse, mutect2, varscan2
- KIF16B | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs368432617; called by muse, mutect2, varscan2
- KIF7 | c.3886C>T p.R1296W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs769783876, COSV51541735, COSV99177101; called by muse, mutect2, varscan2
- KIF9 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.633); catalogued as rs1193418986, COSV55518205, COSV55519636; called by muse, mutect2
- KLC1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs926694130, COSV55808068; called by muse, mutect2, varscan2
- KLRK1 | c.336A>T p.Q112H | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.192); catalogued as COSV53698590; called by muse, mutect2, varscan2
- KRT40 | c.386T>A p.I129N | Missense Mutation (SNP) | VAF 72/536 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.222); catalogued as rs199823333, COSV100898766; called by muse, mutect2, varscan2
- KRT74 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as COSV59771502; called by muse, mutect2, varscan2
- KRTAP5-3 | c.89del p.G30Afs*236 | Frame Shift Del (DEL) | VAF 47/134 reads (35%) | catalogued as COSV101294515; called by mutect2, pindel, varscan2
- LACTB2 | c.258A>G p.I86M | Missense Mutation (SNP) | VAF 187/422 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV52567920; called by muse, mutect2, varscan2
- LAMB1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774870882, COSV55964026, COSV55964780; called by muse, mutect2
- LAMB2 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282468060, COSV59730632; called by muse, mutect2, varscan2
- LANCL1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV52065276; called by muse, mutect2, varscan2
- LARP1B | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs187112542, COSV52797811; called by muse, mutect2, varscan2
- LCA5 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.874); catalogued as COSV63971408; called by muse, mutect2, varscan2
- LGI2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1197547219, COSV101180740, COSV66122851; called by muse, mutect2, varscan2
- LIPE | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303057820, COSV54923008; called by muse, mutect2, varscan2
- LMBRD1 | c.1385G>T p.S462I (on ENST00000649011; = p.S440I on NM_018368.4) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV65297341; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 44/165 reads (27%) | catalogued as rs748712732; called by mutect2, varscan2
- LNPEP | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1445612744, COSV51478106; called by muse, mutect2, varscan2
- LNX1 | c.1351G>A p.A451T (on ENST00000263925 / NM_001126328.3; = p.A355T on NM_032622.2) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as COSV55785838; called by muse, mutect2, varscan2
- LPIN1 | c.2261T>C p.L754P | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773337013, COSV56765750; called by muse, mutect2, varscan2
- LRCH2 | c.1376T>C p.L459P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV57751239; called by muse, mutect2, varscan2
- LRP1B | c.12889G>T p.G4297* | Nonsense Mutation (SNP) | VAF 162/463 reads (35%) | catalogued as COSV67221952; called by muse, mutect2, varscan2
- LRP4 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.045); catalogued as rs1484210878, COSV66135922; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 60/186 reads (32%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC37A3 | c.3912del p.K1304Nfs*11 | Frame Shift Del (DEL) | VAF 76/269 reads (28%) | catalogued as rs1261486978; called by mutect2, pindel, varscan2
- LRRC71 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs539763262, COSV61656242; called by muse, mutect2, varscan2
- LRRFIP1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs201221434; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRTM4 | c.557dup p.L186Ffs*60 | Frame Shift Ins (INS) | VAF 54/167 reads (32%) | catalogued as rs760292106; called by mutect2, pindel, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 43/128 reads (34%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- MACF1 | c.9100G>A p.A3034T | Missense Mutation (SNP) | VAF 124/255 reads (49%) | catalogued as rs1457801660, COSV57121973; called by muse, mutect2, varscan2
- MADD | c.2337del p.P781Lfs*34 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs1187192079; called by mutect2, pindel, varscan2
- MAGED1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs200856189, COSV58515300; called by muse, mutect2, varscan2
- MAN2B1 | c.916T>C p.Y306H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV55472063; called by muse, mutect2, varscan2
- MAN2C1 | c.2254del p.V752Cfs*60 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as COSV51229221; called by mutect2, varscan2
- MAP1B | c.5374T>C p.S1792P | Missense Mutation (SNP) | VAF 165/417 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV57099330; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.54A>C p.E18D | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61010070; called by muse, mutect2, varscan2
- MAP2K4 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62257409, COSV62257489; called by muse, mutect2, varscan2
- MAP7 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | catalogued as COSV63419839; called by muse, mutect2, varscan2
- MASP1 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV51459982; called by muse, varscan2
- MC2R | c.275T>G p.L92R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59618209; called by muse, mutect2
- MCC | c.1751A>G p.K584R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.899); catalogued as rs747962564, COSV56729172; called by muse, varscan2
- MCF2 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV100644361; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 120/232 reads (52%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM3AP | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs758105613, COSV52439947; called by muse, mutect2, varscan2
- MCTP2 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59144353; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 29/161 reads (18%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED8 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs767122202, COSV51941017; called by muse, mutect2, varscan2
- MEGF10 | c.1739A>C p.N580T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV57249408; called by muse, mutect2, varscan2
- MEI1 | c.1902C>A p.C634* | Nonsense Mutation (SNP) | VAF 134/320 reads (42%) | catalogued as COSV100299453; called by mutect2, varscan2
- METTL15 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV57720040; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 26/168 reads (15%) | catalogued as rs780635289; called by mutect2, varscan2
- MID1IP1 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV61230680; called by muse, mutect2, varscan2
- MIER3 | c.1027del p.R343Dfs*15 (on ENST00000381199 / NM_001297599.2; = p.R342Dfs*15 on NM_152622.4) | Frame Shift Del (DEL) | VAF 27/191 reads (14%) | catalogued as COSV67083276; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 60/122 reads (49%) | catalogued as rs546807245; called by mutect2, varscan2
- MITD1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV56806346; called by muse, mutect2, varscan2
- MKI67 | c.1177A>G p.R393G | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV64074460; called by muse, mutect2, varscan2
- MME | c.1781-2A>T p.X594_splice | Splice Site (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100852164; called by muse, mutect2, varscan2
- MMP14 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV61288335; called by muse, mutect2, varscan2
- MPC2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV54796740; called by muse, mutect2, varscan2
- MRGPRX3 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV66933957; called by muse, mutect2, varscan2
- MRNIP | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.275); catalogued as COSV52973129; called by muse, mutect2, varscan2
- MSH6 | c.3280T>C p.S1094P | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.864); catalogued as COSV99314855; called by muse, mutect2, varscan2
- MTCH1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV101010148; called by muse, mutect2, varscan2
- MTHFD2 | c.889+2T>C p.X297_splice | Splice Site (SNP) | VAF 24/130 reads (18%) | catalogued as COSV99902853; called by muse, mutect2, varscan2
- MTO1 | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100940284; called by muse, mutect2, varscan2
- MTREX | c.1662C>A p.G554= | Splice Region (SNP) | VAF 46/115 reads (40%) | catalogued as COSV57926144; called by muse, mutect2, varscan2
- MTTP | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV55505924; called by muse, mutect2, varscan2
- MUC16 | c.27722T>A p.V9241D | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.147); catalogued as COSV67467467; called by muse, mutect2, varscan2
- MUC16 | c.18374C>T p.A6125V | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs775821896, COSV67467472; called by muse, mutect2, varscan2
- MUC16 | c.742T>A p.S248T | Missense Mutation (SNP) | VAF 179/427 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV67467481; called by muse, mutect2, varscan2
- MUC5B | c.6238A>G p.T2080A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.48); catalogued as COSV71592121; called by muse, mutect2, varscan2
- MUC5B | c.7338_7339del p.E2447Vfs*233 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as COSV71592122; called by mutect2, varscan2
- MX1 | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV55819339; called by muse, mutect2, varscan2
- MYBBP1A | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs781028931, COSV54597858; called by muse, varscan2
- MYCBP2 | c.5932A>G p.T1978A (on ENST00000357337; = p.T2016A on NM_015057.5) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs763650115, COSV62019950; called by muse, varscan2
- MYH1 | c.2381C>A p.A794D | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1240226033, COSV56847886, COSV56848732; called by muse, mutect2, varscan2
- MYH10 | c.847A>C p.I283L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV99343855; called by muse, mutect2, varscan2
- MYH11 | c.4072G>A p.A1358T | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV55553883; called by muse, mutect2, varscan2
- MYL6B | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52878829; called by muse, mutect2, varscan2
- MYO18A | c.2202G>T p.E734D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100572675, COSV62866604; called by muse, mutect2
- MYO18A | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs200761046, COSV62866613; called by muse, mutect2, varscan2
- MYO18B | c.7409G>A p.R2470H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs75632091, COSV59130736; called by muse, mutect2, varscan2
- MYO1F | c.231G>A p.A77= | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as rs774761610, COSV57795311; called by muse, varscan2
- MYO3A | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs550530253, COSV56324161, COSV99781993; called by muse, mutect2, varscan2
- MYO3A | c.4663A>G p.S1555G | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV56331536; called by muse, mutect2, varscan2
- MYO5A | c.1727A>G p.Q576R | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.821); catalogued as COSV62560402; called by muse, mutect2, varscan2
- MYO9A | c.3769A>G p.R1257G | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV61851341; called by muse, varscan2
- NBPF10 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs782400929, COSV100743778; called by muse, mutect2, varscan2
- NCKAP5 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201814216, COSV58433575; called by muse, mutect2, varscan2
- NCKAP5 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58444713; called by muse, mutect2, varscan2
- NCOA3 | c.3092G>T p.R1031M | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100507017; called by muse, varscan2
- NCOA6 | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs367600298, COSV62863768; called by muse, mutect2, varscan2
- NCOA6 | c.6007C>T p.P2003S | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.196); catalogued as COSV62863775; called by muse, mutect2, varscan2
- NCOR1 | c.5033T>A p.I1678N | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV51975277; called by muse, mutect2, varscan2
- NDST3 | c.1616A>G p.N539S | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56614140; called by muse, mutect2
- NECTIN4 | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63512763; called by muse, mutect2, varscan2
- NEIL2 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52706831; called by muse, mutect2
- NEK6 | c.559A>C p.K187Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57217803; called by muse, mutect2, varscan2
- NEO1 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56071392; called by muse, mutect2, varscan2
- NETO2 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as rs759414615, COSV57452995; called by muse, mutect2, varscan2
- NID1 | c.1970T>C p.I657T | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs576525237, COSV51620595; called by muse, mutect2, varscan2
- NIN | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769057633, COSV55384519, COSV99815014; called by muse, mutect2, varscan2
- NLN | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1423016963, COSV66765901; called by muse, mutect2, varscan2
- NLRC4 | c.1678C>A p.H560N | Missense Mutation (SNP) | VAF 119/318 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61592742; called by muse, mutect2, varscan2
- NLRC4 | c.972A>C p.Q324H | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61592747; called by muse, mutect2, varscan2
- NLRP10 | c.1686T>G p.D562E | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as COSV60780367; called by muse, mutect2, varscan2
- NLRP12 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs749659859, COSV60745823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763292353, COSV54755400; called by muse, varscan2
- NMNAT2 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as rs1322178575, COSV54268512; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | catalogued as rs759637346; called by mutect2, varscan2
- NPM2 | c.539dup p.L181Afs*13 | Frame Shift Ins (INS) | VAF 18/67 reads (27%) | catalogued as rs770540772; called by mutect2, varscan2
- NPM3 | c.527del p.G176Afs*63 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs771012365; called by mutect2, pindel, varscan2
- NPR2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1373177985, COSV61310800; called by muse, mutect2, varscan2
- NPR2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1217392431, COSV61310807; called by muse, mutect2, varscan2
- NR5A2 | c.1306G>T p.A436S (on ENST00000367362 / NM_205860.3; = p.A390S on NM_003822.5) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52650559; called by muse, mutect2, varscan2
- NRCAM | c.3515G>A p.G1172D (on ENST00000379028 / NM_001371124.1; = p.G1051D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61037390; called by muse, mutect2, varscan2
- NRG2 | c.1376G>A p.S459N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0.097); catalogued as rs1217082793, COSV56829745; called by muse, mutect2, varscan2
- NRK | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs767608122, COSV54597009; called by muse, mutect2, varscan2
- NSRP1 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 99/289 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55933953, COSV55935275; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTNG2 | c.686A>C p.N229T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV62366759; called by muse, mutect2, varscan2
- NTPCR | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1300702585, COSV64052520; called by muse, mutect2, varscan2
- NUGGC | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs778482764, COSV58434914; called by muse, mutect2, varscan2
- NUP153 | c.1011T>A p.N337K | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV50449803; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP98 | c.2131C>A p.H711N | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV61432327, COSV61433079; called by muse, mutect2, varscan2
- ODF1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); catalogued as rs759006752, COSV53432545; called by muse, mutect2, varscan2
- OGT | c.1583G>A p.G528D | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV65480806; called by muse, mutect2, varscan2
- OLFML1 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV100206503, COSV55077235; called by muse, mutect2, varscan2
- OR13A1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV65572436; called by muse, mutect2, varscan2
- OR2B2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as COSV57579748, COSV57580888; called by muse, mutect2, varscan2
- OR2C3 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV63575076; called by muse, mutect2, varscan2
- OR2F2 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283850, COSV68832820; called by muse, mutect2, varscan2
- OR2M2 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 82/620 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62898399; called by muse, mutect2
- OR2T34 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.53); catalogued as COSV100170176; called by muse, mutect2
- OR4B1 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV58882887; called by muse, mutect2, varscan2
- OR51A7 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV63788312, COSV63788913; called by muse, mutect2, varscan2
- OR51B5 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV56176093; called by muse, mutect2, varscan2
- OR51F1 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58579799; called by muse, mutect2, varscan2
- OR52B4 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV68768943; called by muse, mutect2, varscan2
- OR52N1 | c.40T>G p.F14V | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV57693197; called by muse, mutect2, varscan2
- OR5T2 | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.021); catalogued as COSV57589287; called by muse, mutect2, varscan2
- OR6C65 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65568645; called by muse, mutect2, varscan2
- OR6C74 | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV59606506; called by muse, mutect2, varscan2
- OR8B2 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs141277809; called by muse, mutect2, varscan2
- ORC1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs779430952, COSV65363941; called by muse, mutect2, varscan2
- OSBPL11 | c.1768A>G p.N590D | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as COSV56174095; called by muse, mutect2, varscan2
- P2RX7 | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 121/320 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV55855315; called by muse, mutect2, varscan2
- P2RY2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776303; called by muse, mutect2, varscan2
- P4HA2 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV51325649; called by muse, mutect2, varscan2
- PALLD | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV54980907; called by muse, mutect2, varscan2
- PAMR1 | c.1792G>T p.V598L (on ENST00000619888 / NM_001001991.3; = p.V615L on NM_015430.4) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV53512557; called by muse, mutect2, varscan2
- PARP12 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV54934307; called by muse, mutect2, varscan2
- PARP6 | c.1828A>G p.T610A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV99535689; called by muse, mutect2, varscan2
- PATZ1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs763469287, COSV56743865; called by muse, mutect2, varscan2
- PBXIP1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as COSV63777220; called by muse, mutect2
- PC | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1221556887, COSV58992763; called by muse, mutect2
- PCDH9 | c.254T>G p.I85S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60552279; called by muse, mutect2, varscan2
- PCDHA13 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); catalogued as COSV56503062; called by muse, mutect2, varscan2
- PCDHA2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1554119311, COSV65367187; called by muse, mutect2, varscan2
- PCDHA9 | c.2270G>A p.R757K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1554144887, COSV65326735; called by muse, mutect2, varscan2
- PCDHGA11 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as COSV53951842; called by muse, mutect2, varscan2
- PCDHGB1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as rs867459693, COSV53940130; called by muse, mutect2, varscan2
- PCDHGB2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as rs535439542, COSV53898506; called by muse, mutect2
- PCSK1 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1044737470, COSV60735394, COSV60737452; called by muse, mutect2, varscan2
- PCSK5 | c.5401A>C p.S1801R | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV101377226; called by muse, mutect2, varscan2
- PDCD7 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs774717943, COSV52600475; called by muse, mutect2, varscan2
- PDSS1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV66059112; called by muse, varscan2
- PDZD2 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56858703; called by muse, mutect2, varscan2
- PDZRN4 | c.1304T>G p.V435G (on ENST00000402685 / NM_001164595.2; = p.V177G on NM_013377.4) | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100115837, COSV54202110; called by muse, mutect2, varscan2
- PDZRN4 | c.1802A>G p.Q601R (on ENST00000402685 / NM_001164595.2; = p.Q343R on NM_013377.4) | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.196); catalogued as COSV54202123; called by muse, mutect2, varscan2
- PFAS | c.3959C>T p.S1320F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371108457, COSV58980444; called by muse, mutect2, varscan2
- PFKFB1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | PolyPhen benign (0.279); catalogued as rs771700798, COSV66628186; called by muse, mutect2, varscan2
- PGAM1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs371468578; called by muse, mutect2, varscan2
- PHACTR1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60667275; called by muse, mutect2, varscan2
- PHEX | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65075710; called by muse, mutect2, varscan2
- PHF2 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1171243513, COSV100822972; called by muse, mutect2, varscan2
- PHF3 | c.5513C>A p.P1838Q | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV50319580; called by muse, mutect2, varscan2
- PHLPP2 | c.3964G>T p.A1322S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.551); catalogued as COSV62424569; called by muse, mutect2
- PIANP | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57707986; called by muse, mutect2, varscan2
- PIGN | c.2251_2252del p.L751Tfs*8 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs1341720994; called by pindel, varscan2
- PIGR | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs529407537, COSV62903193; called by muse, mutect2, varscan2
- PIK3CG | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs752896730, COSV63248623; called by muse, mutect2
- PIP4P2 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99575077; called by muse, mutect2
- PKD1L1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV56965553; called by muse, mutect2, varscan2
- PKD1L1 | c.3482T>G p.L1161R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56965561; called by muse, mutect2, varscan2
- PKHD1L1 | c.5338G>A p.A1780T | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.071); catalogued as COSV65743357; called by muse, mutect2, varscan2
- PKM | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58788537; called by muse, mutect2, varscan2
- PKM | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs149152236, COSV100064383; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 50/168 reads (30%) | catalogued as rs746999253; called by mutect2, varscan2
- PLAG1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV57611376; called by muse, mutect2, varscan2
- PLCB1 | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV62051577; called by muse, mutect2, varscan2
- PLD1 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100578726, COSV60568208; called by muse, mutect2, varscan2
- PLEKHA6 | c.1634G>T p.R545M | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55333945; called by muse, mutect2, varscan2
- PLK1 | c.1078_1080del p.E360del | In Frame Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs1230691153; called by pindel, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs772701630; called by mutect2, varscan2
- PLPPR4 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100926674, COSV100926676; called by muse, varscan2
- PLXNC1 | c.2426del p.L809* | Frame Shift Del (DEL) | VAF 27/156 reads (17%) | catalogued as rs1392040601; called by mutect2, pindel, varscan2
- PLXND1 | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388658515, COSV60713787; called by muse, mutect2, varscan2
- PNPLA3 | c.943A>C p.S315R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53378361; called by muse, mutect2, varscan2
- PNPLA6 | c.3522del p.S1175Pfs*10 (on ENST00000414982 / NM_001166111.2; = p.S1127Pfs*10 on NM_006702.5) | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as COSV55378573; called by mutect2, varscan2
- POFUT2 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV100499162, COSV57959070; called by muse, mutect2, varscan2
- POLR2A | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs777312684, COSV59492390; called by muse, mutect2, varscan2
- POM121L12 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs755460528, COSV68692870; called by muse, mutect2
- POMC | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775998713, COSV53034904; called by muse, mutect2, varscan2
- POMGNT1 | c.1184A>G p.D395G | Missense Mutation (SNP) | VAF 42/226 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV64339922; called by muse, mutect2, varscan2
- POMGNT2 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs749833091, COSV60953499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs757141424, COSV62892845; called by muse, mutect2, varscan2
- POSTN | c.2036A>T p.E679V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV65713011; called by muse, varscan2
- PPP4R4 | c.1177T>G p.F393V | Missense Mutation (SNP) | VAF 123/377 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV58554730; called by muse, mutect2, varscan2
- PPP4R4 | c.2425A>G p.K809E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV58554740; called by muse, mutect2, varscan2
- PPP5C | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs866767367, COSV50140325; called by muse, mutect2, varscan2
- PPP6R2 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV53293628; called by muse, mutect2
- PRDM2 | c.196del p.R66Dfs*37 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs112778466; called by mutect2, pindel, varscan2
- PRG4 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs772168924, COSV66624029; called by muse, mutect2, varscan2
- PRKRA | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV57868851; called by muse, mutect2, varscan2
- PRMT9 | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs1293501023, COSV56853716; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | catalogued as rs753236928; called by mutect2, varscan2
- PSME3IP1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58429239; called by muse, mutect2
- PTCHD1 | c.2366del p.N789Mfs*8 | Frame Shift Del (DEL) | VAF 45/203 reads (22%) | catalogued as COSV65058929; called by mutect2, pindel, varscan2
- PTER | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as rs370657038; called by muse, mutect2, varscan2
- PTGR2 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50865801; called by muse, mutect2, varscan2
- PTPN14 | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV65284195; called by muse, mutect2, varscan2
- PTPRD | c.4159G>A p.A1387T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61934076; called by muse, mutect2
- PTPRK | c.4130+2T>C p.X1377_splice (on ENST00000368215 / NM_001291984.2; = p.X1378_splice on NM_002844.4) | Splice Site (SNP) | VAF 101/197 reads (51%) | catalogued as COSV100950291; called by muse, mutect2, varscan2
- PUS3 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs1300700932, COSV99916727; called by muse, mutect2
- PWP1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 66/195 reads (34%) | catalogued as rs537077822, COSV69832983; called by muse, mutect2, varscan2
- PXDNL | c.3935C>T p.T1312M | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs780135369, COSV62478598; called by muse, mutect2, varscan2
- QRICH1 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62615592; called by muse, mutect2, varscan2
- QRSL1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 151/249 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV64687083; called by muse, mutect2, varscan2
- RAB41 | c.524C>T p.A175V (on ENST00000374473 / NM_001363807.1; = p.A174V on NM_001032726.3) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52104018, COSV52105039; called by muse, mutect2, varscan2
- RABGAP1L | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1427317164, COSV52296350; called by muse, mutect2, varscan2
- RAI2 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 175/595 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58964355; called by muse, mutect2, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 43/133 reads (32%) | catalogued as rs748033282; called by mutect2, varscan2
- RALGAPA2 | c.3855G>T p.E1285D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99173087; called by muse, mutect2
- RALGAPB | c.535G>C p.A179P | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99484606; called by muse, varscan2
- RAP1B | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV51668624; called by muse, mutect2, varscan2
- RAPGEF1 | c.2791G>T p.A931S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.814); catalogued as COSV64699671, COSV64699813; called by muse, mutect2, varscan2
- RAPGEF1 | c.1752G>T p.K584N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV64699676; called by muse, mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM42 | c.454del p.Q152Rfs*54 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs942828759; called by mutect2, varscan2
- RBMS3 | c.140A>G p.N47S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV56145466; called by muse, mutect2, varscan2
- RBPMS | c.183+1G>A p.X61_splice | Splice Site (SNP) | VAF 45/128 reads (35%) | catalogued as COSV99823555; called by muse, mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 36/205 reads (18%) | catalogued as COSV65365594; called by pindel, varscan2
- REEP3 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs747010885, COSV53424789; called by muse, mutect2, varscan2
- RESF1 | c.707T>C p.F236S | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57022249; called by muse, mutect2, varscan2
- RFC1 | c.2762T>C p.V921A (on ENST00000381897 / NM_001363496.2; = p.V920A on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV62899685; called by muse, mutect2, varscan2
- RFFL | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99265117; called by muse, mutect2
- RGL4 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51943892; called by muse, mutect2, varscan2
- RGS7 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV58542565, COSV58549685; called by muse, mutect2, varscan2
- RHBG | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV54805248; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RICTOR | c.2034del p.K678Nfs*14 | Frame Shift Del (DEL) | VAF 32/182 reads (18%) | catalogued as COSV57124299; called by mutect2, pindel, varscan2
- RIMBP2 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs371234096; called by muse, mutect2, varscan2
- RIMS1 | c.1761G>C p.W587C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53456901; called by muse, mutect2, varscan2
- RIMS3 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV65504348; called by muse, mutect2, varscan2
- RIPOR1 | c.1652C>A p.T551N (on ENST00000379312 / NM_001193522.2; = p.T547N on NM_024519.4) | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV50225082; called by muse, mutect2, varscan2
- RNASE11 | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 15/576 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV100250433; called by muse, mutect2
- RNF214 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs542552815, COSV56118238; called by muse, mutect2, varscan2
- RNF25 | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99828786; called by muse, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel
- ROBO1 | c.1864A>G p.K622E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV71394494; called by muse, mutect2, varscan2
- RPL24 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57245222; called by muse, mutect2, varscan2
- RPP40 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60292101; called by muse, mutect2, varscan2
- RPUSD4 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV53599343; called by muse, mutect2, varscan2
- RSRC2 | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.916); catalogued as COSV59204617; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 50/170 reads (29%) | catalogued as rs759252078; called by mutect2, varscan2
- RTN4RL1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.364); catalogued as COSV100486394; called by muse, mutect2, varscan2
- RYR2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV63686738; called by muse, mutect2, varscan2
- S100A2 | c.79A>C p.K27Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64184728; called by muse, mutect2, varscan2
- SAP130 | c.2732A>G p.Y911C | Missense Mutation (SNP) | VAF 174/497 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52097360; called by muse, mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs763290832; called by mutect2, varscan2
- SCN7A | c.1487A>G p.E496G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV69271681; called by muse, mutect2, varscan2
- SCRN2 | c.437del p.G146Afs*50 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs750983392; called by mutect2, pindel, varscan2
- SDK1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs375595635; called by muse, mutect2, varscan2
- SEC24D | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54879989; called by muse, mutect2, varscan2
- SEC24D | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1395265420, COSV54876555; called by muse, mutect2, varscan2
- SEL1L2 | c.1462T>G p.F488V | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.34); catalogued as COSV53152499; called by muse, mutect2, varscan2
- SEMA4F | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs183645100, COSV60283379; called by mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 40/61 reads (66%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINB6 | c.1168G>A p.G390S (on ENST00000612421 / NM_001271823.2; = p.G371S on NM_004568.6) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762701058, COSV59565070; called by muse, mutect2, varscan2
- SERPINE2 | c.487+2T>G p.X163_splice | Splice Site (SNP) | VAF 39/118 reads (33%) | catalogued as COSV99296288; called by muse, mutect2, varscan2
- SETD1A | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779640618, COSV52687905; called by muse, varscan2
- SETD3 | c.1345A>G p.K449E | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs892597028, COSV59284542; called by muse, mutect2, varscan2
- SETDB1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs749586165, COSV54983075, COSV99645512; called by muse, mutect2, varscan2
- SETX | c.6842+2T>C p.X2281_splice | Splice Site (SNP) | VAF 61/164 reads (37%) | catalogued as COSV99808604; called by muse, mutect2, varscan2
- SETX | c.4921G>A p.V1641I | Missense Mutation (SNP) | VAF 114/366 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56385722; called by muse, mutect2, varscan2
- SEZ6L | c.1741G>T p.D581Y | Missense Mutation (SNP) | VAF 123/319 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50664889, COSV50670140; called by muse, mutect2, varscan2
- SFSWAP | c.1610G>C p.G537A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV55522202; called by muse, mutect2, varscan2
- SFTPA2 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1554851266, COSV100958696; called by mutect2, varscan2
- SGCG | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV54560989; called by muse, mutect2, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/71 reads (25%) | catalogued as rs772386209; called by mutect2, varscan2
- SGSM1 | c.406T>A p.F136I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.146); catalogued as rs1309378732, COSV101240357; called by muse, mutect2, varscan2
- SH3GL2 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66047963; called by muse, mutect2, varscan2
- SHANK1 | c.2534C>A p.A845E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs143486469, COSV53249762; called by muse, mutect2
- SHANK2 | c.2978G>T p.G993V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571749; called by muse, mutect2
- SHOC1 | c.1539del p.K513Nfs*9 | Frame Shift Del (DEL) | VAF 22/187 reads (12%) | catalogued as rs1321256439; called by mutect2, pindel, varscan2
- SHPRH | c.1690T>C p.Y564H | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV51610391; called by muse, mutect2, varscan2
- SIGLECL1 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs768089178, COSV57062036; called by muse, mutect2, varscan2
- SIMC1 | c.2381A>C p.D794A (on ENST00000443967 / NM_001308196.1; = p.D379A on NM_198567.5) | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100055412, COSV53798929; called by muse, mutect2
- SLC12A2 | c.2173A>G p.I725V | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1170586982, COSV52471415; called by muse, mutect2, varscan2
- SLC16A1 | c.565T>G p.C189G | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63709368; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC17A1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs144651108, COSV55076933; called by muse, mutect2, varscan2
- SLC17A2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV55352158, COSV55354923; called by muse, mutect2, varscan2
- SLC19A2 | c.901T>C p.W301R | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52547294; called by muse, mutect2, varscan2
- SLC24A4 | c.839A>G p.D280G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV54112896; called by muse, mutect2, varscan2
- SLC25A44 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63961785; called by muse, mutect2, varscan2
- SLC26A7 | c.1776G>A p.E592= | Splice Region (SNP) | VAF 38/380 reads (10%) | catalogued as rs908857542, COSV52593715; called by muse, mutect2
- SLC26A9 | c.181T>C p.W61R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762646604, COSV61602957; called by muse, mutect2, varscan2
- SLC2A9 | c.1141A>T p.R381* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53321006; called by muse, mutect2, varscan2
- SLC30A8 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69970779; called by muse, mutect2, varscan2
- SLC35A5 | c.898del p.Y300Mfs*8 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | catalogued as rs1363537717; called by mutect2, pindel, varscan2
- SLC36A2 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.06); catalogued as rs774099891, COSV58863348; called by muse, mutect2, varscan2
- SLC39A11 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs145755722, COSV55289039; called by muse, mutect2, varscan2
- SLC45A3 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs771347315, COSV65654957; called by muse, mutect2
- SLC5A1 | c.1931T>C p.V644A | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV56685437; called by muse, mutect2, varscan2
- SLC7A1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1566259880, COSV66330264; called by muse, mutect2, varscan2
- SLC9A5 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV55362177; called by muse, mutect2, varscan2
- SLCO1B3 | c.1199T>A p.F400Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.196); catalogued as COSV53937773; called by muse, mutect2, varscan2
- SLCO1C1 | c.296T>G p.V99G | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56872906, COSV56873569; called by muse, mutect2, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 52/266 reads (20%) | catalogued as rs747319777; called by mutect2, varscan2
- SMCHD1 | c.5213C>T p.A1738V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55257373; called by muse, mutect2, varscan2
- SMTNL1 | c.1276C>T p.R426W (on ENST00000399154; = p.R463W on NM_001105565.2) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs779565620, COSV54702362; called by muse, mutect2, varscan2
- SNAPC3 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV66460311; called by muse, mutect2, varscan2
- SNTB2 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.576); catalogued as COSV60349269; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | catalogued as rs768873484; called by mutect2, varscan2
- SON | c.3268C>T p.R1090W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1407642222, COSV51658220; called by mutect2, varscan2
- SP4 | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 91/271 reads (34%) | catalogued as COSV56022381; called by muse, mutect2, varscan2
- SPAG11A | c.281del p.F94Sfs*43 (on ENST00000642566; = p.F94Sfs*63 on NM_001081552.3) | Frame Shift Del (DEL) | VAF 35/152 reads (23%) | catalogued as rs754013498, COSV58500193; called by mutect2, varscan2
- SPAG17 | c.2093A>C p.D698A | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs181235944, COSV60459222, COSV60468835; called by muse, mutect2, varscan2
- SPATA16 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs139543023; called by muse, mutect2, varscan2
- SPATA18 | c.1522T>G p.L508V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54644894; called by muse, varscan2
- SPDL1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs781266114, COSV99517331; called by muse, varscan2
- SPECC1L | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.197); catalogued as COSV58658539; called by muse, mutect2, varscan2
- SPEF2 | c.700dup p.M234Nfs*13 | Frame Shift Ins (INS) | VAF 191/369 reads (52%) | catalogued as rs528892977; called by mutect2, pindel, varscan2
- SPHKAP | c.3020C>T p.T1007M | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752182241, COSV60868700; called by muse, mutect2, varscan2
- SPRED1 | c.471del p.Q158Sfs*16 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as rs1255149646, COSV100136448; called by mutect2, pindel, varscan2
- SPTAN1 | c.2228A>C p.Q743P | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.781); catalogued as COSV63987240; called by muse, mutect2, varscan2
- SPTB | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs776511812, COSV67631924; called by muse, mutect2, varscan2
- SREBF2 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs1418941693, COSV63331298; called by muse, mutect2, varscan2
- SRRM2 | c.5149C>T p.R1717C | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.828); catalogued as rs146687503; called by muse, mutect2, varscan2
- SRRT | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV53817663; called by muse, mutect2, varscan2
- SRSF9 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV57570448; called by muse, mutect2, varscan2
- SSRP1 | c.1724C>T p.T575M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761799650, COSV53479509; called by muse, mutect2, varscan2
- ST18 | c.1862del p.N621Ifs*10 | Frame Shift Del (DEL) | VAF 76/288 reads (26%) | catalogued as rs1563701552; called by mutect2, varscan2
- ST8SIA2 | c.289A>G p.R97G | Missense Mutation (SNP) | VAF 82/195 reads (42%) | PolyPhen probably damaging (0.994); catalogued as COSV51569611; called by muse, mutect2, varscan2
- ST8SIA5 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 19/95 reads (20%) | PolyPhen probably damaging (0.926); catalogued as COSV59332006; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 60/186 reads (32%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAC | c.571+2T>C p.X191_splice | Splice Site (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99829294; called by muse, mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 140/280 reads (50%) | catalogued as rs746501298; called by mutect2, varscan2
- STK16 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV50278280; called by muse, mutect2, varscan2
- STK32B | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747981829, COSV51511205; called by mutect2, varscan2
- STK36 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760186885, COSV55307516; called by muse, mutect2, varscan2
- STK36 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55326695; called by muse, mutect2, varscan2
- STOML2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs753222022, COSV58926596; called by muse, mutect2, varscan2
625 further variants in this file (328 protein-altering or splice-affecting, 269 silent, 28 other) are not listed here.
